Somatic mutation profile of tumor specimen TCGA-KS-A4ID-01A (aliquot TCGA-KS-A4ID-01A-11D-A257-08) from TCGA case TCGA-KS-A4ID, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.9 years (20,413 days).
Specimen TCGA-KS-A4ID-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae6de902-7eaf-491d-8442-0cc61572e7e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4ID-11A (Solid Tissue Normal), aliquot TCGA-KS-A4ID-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad5e3129-8bcf-4df9-8dcc-a19afd382595

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPTF | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV100074238; called by muse, mutect2, varscan2
- HSP90AA1 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 36/165 reads (22%) | catalogued as COSV99355054; called by muse, mutect2, varscan2
- MARK3 | c.1637G>T p.S546I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.339); catalogued as COSV99357868; called by muse, mutect2, varscan2
- OR5M3 | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56567183; called by muse, mutect2
- PCNX1 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.188); catalogued as COSV99454346; called by muse, mutect2
- RIMBP2 | c.1884C>A p.S628R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV99898544; called by muse, mutect2, varscan2
- SLIT3 | c.4253A>G p.H1418R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.045); catalogued as COSV100265673; called by mutect2, varscan2
- GLRB | c.807C>T p.Y269= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1021238246, COSV100029510; called by muse, mutect2, varscan2
- PRDM7 | c.1074G>C p.G358= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs753521349, COSV100371089; called by muse, mutect2, varscan2
- TNFAIP2 | c.927C>T p.P309= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV100280842; called by muse, mutect2, varscan2
